Somatic mutation profile of tumor specimen MP2PRT-PARBMX-TMP1-A (aliquot MP2PRT-PARBMX-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARBMX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.8 years (3,956 days).
Specimen MP2PRT-PARBMX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56b40b8f-365e-4bc1-8ca2-e6ab5a7a7cb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBMX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBMX-NM1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b460977-f1c6-42cd-8289-29be1d3759ff

The open-access MAF lists 36 somatic variants for this specimen: 31 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Frame Shift Ins 3, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTM1 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 160/607 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs132630303, CM970995; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 100/361 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs138438667, COSV101184550; called by muse, varscan2
- BCL11B | c.2147C>T p.A716V (on ENST00000357195 / NM_001282237.2; = p.A645V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 227/736 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761140637, COSV61737714; called by muse, mutect2, varscan2
- BCL2L14 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 149/358 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1473390156, COSV53786446; called by muse, mutect2, varscan2
- BMP5 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as rs376630543; called by muse, mutect2, varscan2
- CCDC114 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 256/542 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759075558; called by muse, mutect2, varscan2
- CNTN6 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777602103; called by muse, mutect2, varscan2
- FRMPD3 | c.4883G>A p.R1628Q | Missense Mutation (SNP) | VAF 256/885 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762374528, COSV52189908; called by muse, mutect2, varscan2
- GAPVD1 | c.3124C>T p.R1042W (on ENST00000394104; = p.R1069W on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs377753350; called by muse, mutect2, varscan2
- IGSF5 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 182/742 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200941561; called by muse, mutect2, varscan2
- MAGEB6 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 209/737 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs773473561, COSV66873048; called by muse, varscan2
- MKI67 | c.4991C>G p.T1664R | Missense Mutation (SNP) | VAF 184/707 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV64072774; called by mutect2, varscan2
- MMRN1 | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 131/430 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV53338024; called by muse, mutect2, varscan2
- MYH3 | c.4148G>A p.R1383H | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs143574829; called by muse, varscan2
- NKX6-2 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 283/818 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs563679091; called by muse, mutect2, varscan2
- PCDH7 | c.794C>G p.A265G | Missense Mutation (SNP) | VAF 316/993 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.403); catalogued as COSV62337802; called by muse, mutect2, varscan2
- PLCL1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70862954; called by muse, mutect2, varscan2
- SLC2A7 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs750945721; called by muse, mutect2, varscan2
- TRIM75P | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 120/398 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs376170632; called by muse, mutect2, varscan2
- VWA3B | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 176/430 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68243196; called by muse, mutect2
- ZP3 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as rs768441500, COSV60635649; called by muse, mutect2, varscan2
- DCC | c.3884C>A p.A1295E | Missense Mutation (SNP) | VAF 135/426 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EDEM1 | c.1328C>G p.P443R | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRFN2 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 214/445 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LZTR1 | c.2219_2219+2del | In Frame Del (DEL) | VAF 118/254 reads (46%) | called by mutect2, pindel, varscan2
- MGA | c.1384_1385insCCCCCCG p.D462Afs*23 | Frame Shift Ins (INS) | VAF 107/272 reads (39%) | called by mutect2, pindel, varscan2
- PRMT3 | c.49_50insGG p.N17Rfs*77 | Frame Shift Ins (INS) | VAF 171/487 reads (35%) | called by pindel, varscan2
- SPATC1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 271/911 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STXBP5 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XBP1 | c.577dup p.V193Gfs*194 | Frame Shift Ins (INS) | VAF 101/268 reads (38%) | called by mutect2, pindel, varscan2
- ZNF333 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 153/409 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GRIA3 | c.936C>T p.D312= | Silent (SNP) | VAF 120/430 reads (28%) | catalogued as rs1348055128, COSV52075945; called by muse, mutect2, varscan2
- OR8A1 | c.54G>A p.T18= | Silent (SNP) | VAF 211/475 reads (44%) | catalogued as rs147478128; called by muse, mutect2, varscan2
- RBM5 | c.1047A>G p.Q349= | Silent (SNP) | VAF 93/223 reads (42%) | called by muse, mutect2, varscan2
- TEX11 | c.468C>T p.Y156= (on ENST00000344304; = p.Y141= on NM_031276.3) | Silent (SNP) | VAF 117/353 reads (33%) | catalogued as rs1485537363, COSV100721375; called by muse, mutect2, varscan2
- NECTIN2 | c.1042+3778C>T | Intron (SNP) | VAF 184/426 reads (43%) | catalogued as rs769290208; called by muse, varscan2
